Somatic mutation profile of tumor specimen TCGA-02-0055-01A (aliquot TCGA-02-0055-01A-01D-1490-08) from TCGA case TCGA-02-0055, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 62.4 years (22,798 days).
Specimen TCGA-02-0055-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e1d1044b-db2b-464c-988f-5cb83e6b7ff3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-02-0055-10A (Blood Derived Normal), aliquot TCGA-02-0055-10A-01D-1490-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d768978e-7ff1-4324-89ef-f39018a3cfae

The open-access MAF lists 55 somatic variants for this specimen: 39 protein-altering or splice-affecting, 13 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 13, Intron 3, Splice Region 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.646G>A p.V216M | Missense Mutation (SNP) | VAF 38/64 reads (59%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730882025, CM159291, CX952222, COSV52671096, COSV52751864, COSV53384298; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACP7 | c.1168G>A p.V390M | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.129); catalogued as rs546523874, COSV58700546; called by muse, mutect2, varscan2
- AFM | c.773T>C p.L258P | Missense Mutation (SNP) | VAF 65/182 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs139224995; called by muse, mutect2, varscan2
- ALDH1A2 | c.1435G>A p.A479T | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as COSV51088545; called by muse, mutect2, varscan2
- ARMC3 | c.697G>A p.G233R | Missense Mutation (SNP) | VAF 31/50 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV104401608, COSV53062158; called by muse, mutect2, varscan2
- C8B | c.1676G>A p.G559E | Missense Mutation (SNP) | VAF 49/165 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.134); catalogued as COSV64777927; called by muse, mutect2, varscan2
- CENPF | c.56A>G p.K19R | Missense Mutation (SNP) | VAF 56/157 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65275452; called by muse, mutect2, varscan2
- CLDN6 | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs369700162; called by muse, mutect2, varscan2
- COL11A1 | c.2479C>T p.P827S | Missense Mutation (SNP) | VAF 64/149 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV62185064; called by muse, mutect2, varscan2
- COL6A3 | c.5167C>T p.L1723F | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.42); catalogued as COSV55092157, COSV55098789; called by muse, mutect2, varscan2
- DEFB118 | c.154C>T p.R52* | Nonsense Mutation (SNP) | VAF 64/203 reads (32%) | catalogued as rs34328728, COSV53620388; called by muse, mutect2, varscan2
- DLGAP4 | c.1448G>A p.C483Y | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.854); catalogued as rs757121791, COSV59418506; called by muse, mutect2, varscan2
- FAM153CP | n.387G>A | Splice Region (SNP) | VAF 162/458 reads (35%) | catalogued as rs1321075624, COSV67752645; called by muse, mutect2, varscan2
- FLNB | c.2357G>A p.R786Q | Missense Mutation (SNP) | VAF 52/407 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.466); catalogued as rs142314034, COSV99911646; called by muse, mutect2, varscan2
- GABRA3 | c.1351A>T p.S451C | Missense Mutation (SNP) | VAF 98/364 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.819); catalogued as COSV64799572; called by muse, mutect2, varscan2
- GEMIN8 | c.476G>A p.R159Q | Missense Mutation (SNP) | VAF 97/242 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.951); catalogued as rs749314407, COSV60550720; called by muse, mutect2, varscan2
- H2BW1 | c.331C>T p.H111Y | Missense Mutation (SNP) | VAF 51/118 reads (43%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.986); catalogued as COSV54220428, COSV99475096; called by muse, mutect2, varscan2
- HGFAC | c.1372G>A p.V458I | Missense Mutation (SNP) | VAF 100/323 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs759171739, COSV66976946; called by muse, mutect2, varscan2
- HOOK1 | c.180A>T p.L60F | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); catalogued as COSV64620466; called by muse, mutect2, varscan2
- ITPR1 | c.5966G>A p.R1989H (on ENST00000354582; = p.R1934H on NM_002222.7) | Missense Mutation (SNP) | VAF 97/336 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762758498, COSV56984496; called by muse, mutect2, varscan2
- KDM7A | c.938G>A p.R313H | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs369398521; called by muse, mutect2, varscan2
- KLHL34 | c.1241C>T p.A414V | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.46); catalogued as rs1350335319, COSV65279503; called by muse, mutect2, varscan2
- OCA2 | c.1657G>C p.V553L | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.869); catalogued as COSV62339253, COSV62347333; called by muse, mutect2, varscan2
- P2RY8 | c.982G>A p.A328T | Missense Mutation (SNP) | VAF 62/193 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as COSV101183919, COSV67177482; called by muse, mutect2, varscan2
- P3H3 | c.1727G>A p.R576H | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781997100, COSV51835707; called by muse, mutect2, varscan2
- PCDHGA1 | c.2149C>T p.R717W | Missense Mutation (SNP) | VAF 69/169 reads (41%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.028); catalogued as rs769608961, COSV65298696; called by muse, mutect2, varscan2
- PHRF1 | c.2924A>T p.D975V (on ENST00000264555 / NM_001286581.2; = p.D974V on NM_020901.4) | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.084); catalogued as COSV52760765; called by muse, mutect2, varscan2
- PICALM | c.359T>A p.M120K | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV62671126; called by muse, mutect2, varscan2
- PLAG1 | c.1083G>A p.M361I | Missense Mutation (SNP) | VAF 97/314 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.258); catalogued as COSV57611789; called by muse, varscan2
- PPIG | c.2261G>C p.G754A | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV53645336; called by muse, mutect2, varscan2
- PTEN | c.391A>G p.T131A | Missense Mutation (SNP) | VAF 97/191 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64289201, COSV64295760, COSV64303726; called by muse, mutect2, varscan2
- SCNN1B | c.118C>T p.R40C | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754549610, COSV56301412; called by muse, mutect2, varscan2
- SLC27A6 | c.100G>A p.V34M | Missense Mutation (SNP) | VAF 36/252 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as rs748879688, COSV52486573; called by muse, mutect2, varscan2
- TPST2 | c.328C>T p.R110C | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1390379598, COSV58680089; called by muse, mutect2, varscan2
- TRPM1 | c.1220C>T p.P407L | Missense Mutation (SNP) | VAF 53/152 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as rs747756548, COSV56635730; called by muse, mutect2, varscan2
- TTN | c.89167A>G p.K29723E (on ENST00000591111; = p.K22299E on NM_003319.4) | Missense Mutation (SNP) | VAF 35/76 reads (46%) | PolyPhen probably damaging (0.994); catalogued as COSV60273196; called by muse, mutect2, varscan2
- ZNF248 | c.107T>C p.V36A | Missense Mutation (SNP) | VAF 104/214 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV61997830; called by muse, mutect2, varscan2
- ZNF81 | c.1609G>A p.D537N | Missense Mutation (SNP) | VAF 54/192 reads (28%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.755); catalogued as rs782066048, COSV58576597; called by muse, mutect2, varscan2
- RB1 | c.799_836del p.L267Rfs*3 | Frame Shift Del (DEL) | VAF 24/76 reads (32%) | called by mutect2, pindel
- ASXL1 | c.1830C>T p.G610= | Silent (SNP) | VAF 30/100 reads (30%) | catalogued as rs199829982; called by muse, mutect2, varscan2
- CSAG3 | c.186C>T p.D62= | Silent (SNP) | VAF 80/666 reads (12%) | catalogued as rs1463213424; called by muse, varscan2
- ERCC6L | c.3678G>A p.A1226= | Silent (SNP) | VAF 41/157 reads (26%) | catalogued as rs961551484, COSV57820856; called by muse, mutect2, varscan2
- FAT4 | c.11286G>A p.T3762= | Silent (SNP) | VAF 16/252 reads (6%) | catalogued as rs1304302008, COSV58702976; called by muse, mutect2
- FGD5 | c.2613G>A p.S871= | Silent (SNP) | VAF 44/122 reads (36%) | catalogued as rs267599640, COSV53244287; called by muse, mutect2, varscan2
- KRTAP19-3 | c.12C>T p.Y4= | Silent (SNP) | VAF 96/303 reads (32%) | catalogued as rs376412934, COSV61854474; called by muse, mutect2
- MATN2 | c.2541T>C p.S847= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as COSV54717669; called by muse, mutect2, varscan2
- OR2A2 | c.573C>T p.T191= | Silent (SNP) | VAF 74/320 reads (23%) | catalogued as COSV68871735; called by muse, mutect2, varscan2
- OR2L13 | c.357C>T p.Y119= | Silent (SNP) | VAF 136/441 reads (31%) | catalogued as rs1438157332, COSV63553802; called by muse, mutect2, varscan2
- OR51D1 | c.567C>T p.H189= | Silent (SNP) | VAF 58/251 reads (23%) | catalogued as COSV62914271; called by muse, mutect2, varscan2
- TBX22 | c.963C>T p.G321= | Silent (SNP) | VAF 30/252 reads (12%) | catalogued as COSV64787452; called by muse, mutect2, varscan2
- USP11 | c.1824C>T p.Y608= (on ENST00000218348; = p.Y565= on NM_001371072.1) | Silent (SNP) | VAF 52/197 reads (26%) | catalogued as rs762232804, COSV54473937; called by muse, mutect2, varscan2
- ZC3H12D | c.69G>T p.V23= | Silent (SNP) | VAF 13/28 reads (46%) | catalogued as COSV66324980; called by muse, mutect2, varscan2
- DNM3 | c.1689+7578G>A | Intron (SNP) | VAF 8/12 reads (67%) | catalogued as COSV100798413; called by muse, varscan2
- DST | c.4296+4498_4296+4502dup | Intron (INS) | VAF 57/204 reads (28%) | called by mutect2, varscan2
- Z82195.2 | n.416-19552G>A | Intron (SNP) | VAF 19/70 reads (27%) | catalogued as rs1255673256; called by muse, mutect2, varscan2
